Somatic mutation profile of tumor specimen BLGSP-71-08-00029-01A (aliquot BLGSP-71-08-00029-01A-01D-A663-33) from CGCI case BLGSP-71-08-00029, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 10.9 years (3,970 days).
Specimen BLGSP-71-08-00029-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Liver; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66411eaa-6258-47c5-9a5a-2637af66ebb9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00029-10A (Blood Derived Normal), aliquot BLGSP-71-08-00029-10A-01D-A663-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91f96837-d18a-4786-8d87-040dd0f72bf7

The open-access MAF lists 14 somatic variants for this specimen: 7 protein-altering or splice-affecting, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 5'Flank 4, Intron 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.125A>G p.Y42C | Missense Mutation (SNP) | VAF 144/360 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1057519954, COSV69041523, COSV69041892, COSV69042190; ClinVar: likely pathogenic; called by muse, varscan2
- ETS1 | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.539); catalogued as COSV60095088; called by muse, varscan2
- HMCN1 | c.16120C>T p.R5374W | Missense Mutation (SNP) | VAF 52/416 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs774597838, COSV54874102; called by muse, mutect2, varscan2
- MYC | c.746G>C p.S249T (on ENST00000377970; = p.S264T on NM_002467.6) | Missense Mutation (SNP) | VAF 102/214 reads (48%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.966); catalogued as COSV52367372, COSV52368669, COSV52378900; called by muse, varscan2
- FSIP2 | c.5241A>C p.E1747D | Missense Mutation (SNP) | VAF 105/212 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- KMT2C | c.8989C>T p.Q2997* | Nonsense Mutation (SNP) | VAF 147/356 reads (41%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.2635G>C p.V879L | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); called by muse, mutect2
- BCL7A | chr12:122020721 A>G | 5'Flank (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2
- CXCR4 | c.15+491G>A | Intron (SNP) | VAF 92/171 reads (54%) | called by muse, varscan2
- CXCR4 | c.15+479C>T | Intron (SNP) | VAF 56/173 reads (32%) | catalogued as rs541717360, COSV54016646; called by muse, varscan2
- CXCR4 | c.15+370T>A | Intron (SNP) | VAF 16/177 reads (9%) | catalogued as rs571084269, COSV54016669; called by muse, mutect2
- TMSB4X | chrX:12975453 G>A | 5'Flank (SNP) | VAF 53/59 reads (90%) | catalogued as rs1042591739; called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331919 C>A | 5'Flank (SNP) | VAF 74/176 reads (42%) | called by muse, varscan2
- TSPOAP1 | chr17:58331951 C>T | 5'Flank (SNP) | VAF 82/182 reads (45%) | called by muse, varscan2
